Somatic mutation profile of tumor specimen TCGA-DM-A28K-01A (aliquot TCGA-DM-A28K-01A-21D-A16V-10) from TCGA case TCGA-DM-A28K, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Hepatic flexure of colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 75.1 years (27,428 days).
Specimen TCGA-DM-A28K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5dac96c1-1efa-464c-989c-3561dae0f52d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DM-A28K-10A (Blood Derived Normal), aliquot TCGA-DM-A28K-10A-01D-A16V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/948e994f-4232-443a-b802-dcce9f208b90

The open-access MAF lists 115 somatic variants for this specimen: 83 protein-altering or splice-affecting, 31 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 31, Frame Shift Ins 4, Splice Site 3, Nonsense Mutation 2, Frame Shift Del 2, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 36/64 reads (56%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- ATM | c.9023G>A p.R3008H | Missense Mutation (SNP) | VAF 36/84 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs587781894, CM092589, COSV53726175, COSV53741856; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ING1 | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 61/72 reads (85%) | hotspot (GDC flag); catalogued as COSV58167363; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 69/168 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.692dup p.S232Qfs*3 | Frame Shift Ins (INS) | VAF 26/51 reads (51%) | catalogued as rs377767334, COSV61691229; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA3 | c.5098G>A p.A1700T | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs745625493, COSV57051086; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACLY | c.1990G>A p.G664R | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1286816033, COSV100709588, COSV61249811; called by muse, mutect2, varscan2
- ADAM11 | c.1288G>T p.G430C | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52345106; called by muse, mutect2, varscan2
- ADAMTS7 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.53); PolyPhen benign (0.01); catalogued as rs1010641725, COSV66306391; called by muse, mutect2, varscan2
- AGAP4 | c.1049A>T p.D350V | Missense Mutation (SNP) | VAF 86/218 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV101432700, COSV71165063; called by muse, mutect2, varscan2
- AKAP12 | c.4331T>G p.L1444W | Missense Mutation (SNP) | VAF 26/31 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53571640; called by muse, mutect2, varscan2
- ANO5 | c.2686G>A p.A896T | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV61083307; called by muse, mutect2, varscan2
- ANPEP | c.1555G>A p.D519N | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV55590202; called by muse, mutect2, varscan2
- ARHGEF17 | c.2846G>A p.R949Q | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs775779249, COSV55230876; called by muse, mutect2, varscan2
- BMPR1A | c.1021G>C p.G341R | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64405338; called by muse, mutect2, varscan2
- BRPF3 | c.2774G>A p.R925H | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.362); catalogued as rs1337109208, COSV60206587; called by muse, mutect2, varscan2
- CACNA1S | c.3539A>G p.D1180G | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62937726; called by muse, mutect2, varscan2
- CBLIF | c.1194G>T p.G398= | Splice Region (SNP) | VAF 47/124 reads (38%) | catalogued as COSV99951069; called by muse, mutect2, varscan2
- CCDC88A | c.3095G>A p.R1032Q | Missense Mutation (SNP) | VAF 109/291 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.044); catalogued as rs201678253, COSV55058606; called by muse, mutect2, varscan2
- CLDN12 | c.481C>A p.L161M | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.056); catalogued as COSV55306473; called by muse, mutect2, varscan2
- CLK1 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV58432867; called by muse, mutect2, varscan2
- DCHS1 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs143832439, COSV55043644; called by muse, mutect2, varscan2
- DMBX1 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1424205121, COSV63601784; called by muse, mutect2, varscan2
- DZIP1 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV61264659; called by muse, mutect2, varscan2
- EDC4 | c.3739C>T p.R1247C | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs372202506; called by muse, mutect2, varscan2
- EML1 | c.1520G>A p.R507Q | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as rs1444645451, COSV51742798; called by muse, mutect2, varscan2
- ERC2 | c.1118C>T p.T373M | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753457037, COSV55609467; called by muse, mutect2, varscan2
- ETS2 | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV62872572; called by muse, mutect2, varscan2
- FAIM | c.467G>A p.S156N | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100623999; called by muse, mutect2, varscan2
- FAM89B | c.452C>T p.S151F (on ENST00000530349 / NM_001098785.2; = p.S138F on NM_152832.3) | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV57079174; called by muse, mutect2, varscan2
- FBH1 | c.514C>T p.R172W (on ENST00000362091 / NM_178150.3; = p.R223W on NM_032807.4) | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs143001244; called by muse, mutect2, varscan2
- FBXL7 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.67); catalogued as rs775944574, COSV61640916, COSV61651772; called by muse, mutect2, varscan2
- FLVCR1 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs1009263236, COSV63133957; called by muse, mutect2, varscan2
- GLG1 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs776142455, COSV52664938, COSV99215095; called by muse, mutect2, varscan2
- GPRIN1 | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs528434134, COSV99992076; called by muse, mutect2
- GUCY2F | c.2641G>T p.D881Y | Missense Mutation (SNP) | VAF 95/110 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54299861; called by muse, mutect2, varscan2
- HBD | c.340G>A p.V114M | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.538); catalogued as COSV99496846; called by muse, mutect2, varscan2
- HECTD1 | c.4944G>T p.E1648D | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.931); catalogued as COSV67945571; called by muse, mutect2, varscan2
- HK3 | c.1424G>A p.R475H | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756923182, COSV52837972; called by muse, mutect2, varscan2
- HTRA3 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs746960044, COSV56470226; called by muse, mutect2, varscan2
- IGFN1 | c.2708C>G p.T903S (on ENST00000295591 / NM_001367841.1; = p.T3360S on NM_001164586.2) | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.068); catalogued as COSV55168675; called by muse, mutect2, varscan2
- IGHM | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.691); catalogued as rs781852051; called by muse, mutect2, varscan2
- INTS8 | c.2260C>T p.R754W | Missense Mutation (SNP) | VAF 112/195 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs372594000; called by muse, mutect2, varscan2
- KRT2 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 59/117 reads (50%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.446); catalogued as rs530180060, COSV59008994; called by muse, mutect2, varscan2
- LPCAT1 | c.1025+1G>A p.X342_splice | Splice Site (SNP) | VAF 38/65 reads (58%) | catalogued as COSV52036366; called by muse, mutect2, varscan2
- MAMLD1 | c.395A>G p.E132G | Missense Mutation (SNP) | VAF 21/23 reads (91%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.621); catalogued as COSV53373136; called by muse, mutect2, varscan2
- MECOM | c.218C>T p.T73M (on ENST00000468789 / NM_001105078.4; = p.T261M on NM_004991.4) | Missense Mutation (SNP) | VAF 68/154 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs146635720; called by muse, mutect2, varscan2
- MINAR1 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as rs369106668; called by muse, mutect2, varscan2
- MUC17 | c.10226C>T p.T3409M | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs150801786; called by muse, mutect2, varscan2
- MYO15A | c.10083-1G>A p.X3361_splice | Splice Site (SNP) | VAF 10/23 reads (43%) | catalogued as COSV52753967; called by muse, mutect2, varscan2
- NEUROG3 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 93/231 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as COSV54342438; called by muse, mutect2, varscan2
- NKAIN3 | c.209C>A p.A70D | Missense Mutation (SNP) | VAF 93/304 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60653786; called by muse, mutect2, varscan2
- NMUR2 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.889); catalogued as rs1165311256, COSV99677222; called by muse, mutect2, varscan2
- NRGN | c.83C>A p.A28E | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.801); catalogued as COSV99423451, COSV99423565; called by muse, mutect2, varscan2
- OR1Q1 | c.247C>A p.Q83K | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.062); catalogued as COSV52917499, COSV99939330; called by muse, mutect2, varscan2
- OR5B3 | c.167C>A p.P56H | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV58676383, COSV58676603; called by muse, mutect2, varscan2
- PCDHA4 | c.1904G>A p.R635H | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.9); catalogued as rs376395074, COSV63543797; called by muse, mutect2, varscan2
- PCDHB8 | c.1333G>A p.V445I | Missense Mutation (SNP) | VAF 63/279 reads (23%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); catalogued as COSV50757950; called by muse, mutect2, varscan2
- PHLDB1 | c.1397G>A p.R466Q | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as rs140294013, COSV100616796; called by muse, mutect2, varscan2
- PRDM9 | c.1315C>T p.Q439* | Nonsense Mutation (SNP) | VAF 69/245 reads (28%) | catalogued as COSV57003775, COSV57004130; called by muse, mutect2, varscan2
- PSG1 | c.560T>A p.L187H | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54946410; called by muse, mutect2, varscan2
- RAB6C | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 53/230 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.009); catalogued as COSV69339949; called by muse, mutect2, varscan2
- RRP12 | c.1846G>A p.D616N | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.404); catalogued as rs202239906, COSV59664644; called by muse, varscan2
- SPATA2L | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs760286527, COSV57046260; called by muse, mutect2, varscan2
- SPEF2 | c.2657del p.K886Rfs*8 | Frame Shift Del (DEL) | VAF 15/122 reads (12%) | catalogued as rs750890082; called by mutect2, varscan2
- SRPK1 | c.1567C>G p.L523V | Missense Mutation (SNP) | VAF 127/264 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100644429, COSV60412237; called by muse, mutect2, varscan2
- STAB2 | c.5375C>A p.A1792D | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.085); catalogued as COSV66336458; called by muse, mutect2, varscan2
- STARD3 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.614); catalogued as rs544183170, COSV59223274; called by muse, mutect2, varscan2
- TIMELESS | c.3193C>T p.R1065C | Missense Mutation (SNP) | VAF 63/152 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.821); catalogued as rs371723339; called by muse, mutect2, varscan2
- TRIM45 | c.1426G>A p.V476I | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs533016681, COSV56712893; called by muse, mutect2, varscan2
- TRIM51 | c.1282A>C p.S428R | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.177); catalogued as COSV55270325; called by muse, mutect2
- TRIM52 | c.201G>C p.E67D | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs146030758; called by muse, mutect2, varscan2
- TRIM9 | c.622C>G p.R208G | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.375); catalogued as rs746028500, COSV100032063; called by muse, mutect2
- TXLNB | c.839A>G p.E280G | Missense Mutation (SNP) | VAF 174/380 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV62727208; called by muse, mutect2, varscan2
- UEVLD | c.887-1G>C p.X296_splice | Splice Site (SNP) | VAF 17/43 reads (40%) | catalogued as COSV57873687; called by muse, mutect2, varscan2
- UGT2A3 | c.108G>C p.W36C | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52359385, COSV99280171; called by muse, mutect2, varscan2
- WDR90 | c.4544C>T p.T1515M | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.121); catalogued as rs766903229, COSV53466599; called by muse, mutect2, varscan2
- ZNF320 | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.605); catalogued as COSV67089026; called by muse, mutect2, varscan2
- ZNF423 | c.272C>T p.T91M (on ENST00000563137 / NM_001379286.1; = p.T83M on NM_015069.4) | Missense Mutation (SNP) | VAF 55/114 reads (48%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.576); catalogued as rs200710667, COSV52181840; called by muse, mutect2, varscan2
- ZSCAN1 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.433); catalogued as rs771707739, COSV56602345; called by muse, mutect2, varscan2
- AMER1 | c.1452_1476del p.E485Ifs*48 | Frame Shift Del (DEL) | VAF 32/49 reads (65%) | called by mutect2, pindel, varscan2
- CDYL | c.222dup p.G75Rfs*13 (on ENST00000328908 / NM_001368125.1; = p.G21Rfs*13 on NM_004824.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 59/174 reads (34%) | called by mutect2, pindel, varscan2
- SOX9 | c.916dup p.V306Gfs*272 | Frame Shift Ins (INS) | VAF 6/23 reads (26%) | called by mutect2, pindel
- ANO4 | c.1359T>A p.A453= (on ENST00000392977 / NM_001286615.2; = p.A418= on NM_178826.4) | Silent (SNP) | VAF 70/182 reads (38%) | catalogued as COSV54589616; called by muse, mutect2, varscan2
- APOB | c.2676G>A p.P892= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as rs759072451, COSV51928456; called by muse, mutect2, varscan2
- ATP10D | c.3786C>T p.S1262= | Silent (SNP) | VAF 86/200 reads (43%) | catalogued as COSV56705356; called by muse, mutect2, varscan2
- CHD5 | c.1194C>T p.D398= | Silent (SNP) | VAF 30/62 reads (48%) | catalogued as COSV52408129; called by muse, mutect2, varscan2
- CLDND2 | c.378C>T p.F126= | Silent (SNP) | VAF 55/166 reads (33%) | catalogued as COSV52467256; called by muse, mutect2, varscan2
- CSMD2 | c.7356C>T p.H2452= | Silent (SNP) | VAF 87/194 reads (45%) | catalogued as rs148445270; called by muse, mutect2, varscan2
- DCLK1 | c.1062G>A p.T354= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV55178093; called by muse, mutect2, varscan2
- DMXL2 | c.8175T>C p.Y2725= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as COSV51842665; called by muse, mutect2, varscan2
- EBF3 | c.1518G>A p.S506= (on ENST00000355311 / NM_001375392.1; = p.S497= on NM_001005463.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs372476626; called by muse, mutect2, varscan2
- FEZF2 | c.1254G>A p.T418= | Silent (SNP) | VAF 88/205 reads (43%) | catalogued as COSV99334987; called by muse, mutect2, varscan2
- FLNA | c.4833C>T p.D1611= | Silent (SNP) | VAF 62/73 reads (85%) | catalogued as rs1444219497, COSV61040079; called by muse, mutect2, varscan2
- FREM2 | c.6768C>T p.T2256= | Silent (SNP) | VAF 61/127 reads (48%) | catalogued as COSV54832127; called by muse, mutect2, varscan2
- GLI4 | c.720G>A p.E240= | Silent (SNP) | VAF 23/87 reads (26%) | catalogued as COSV60681729; called by muse, mutect2, varscan2
- IRF2BPL | c.1857C>T p.N619= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as rs549022469, COSV53146471, COSV53148346; called by muse, mutect2, varscan2
- LCE2C | c.138T>C p.S46= | Silent (SNP) | VAF 97/165 reads (59%) | catalogued as rs770983033, COSV64228357; called by muse, mutect2, varscan2
- LMOD2 | c.1269T>C p.P423= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV101505462; called by muse, varscan2
- MAP4K4 | c.2100C>T p.S700= (on ENST00000347699 / NM_001242559.2; = p.S615= on NM_004834.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as rs376560483; called by muse, mutect2, varscan2
- MSGN1 | c.561G>A p.E187= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs375039406; called by muse, mutect2, varscan2
- OR2T33 | c.366G>A p.A122= | Silent (SNP) | VAF 100/455 reads (22%) | catalogued as rs757226382, COSV58813596, COSV58814743; called by muse, mutect2, varscan2
- P2RY8 | c.981C>T p.S327= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as rs184360195, COSV67176961; called by muse, mutect2, varscan2
- PAXBP1 | c.801C>T p.D267= | Silent (SNP) | VAF 44/158 reads (28%) | catalogued as rs761789368, COSV51608352; called by muse, mutect2, varscan2
- PCDHB10 | c.1089G>A p.T363= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as rs1554284127, COSV53375219; called by muse, mutect2
- PCDHGA7 | c.360C>T p.D120= | Silent (SNP) | VAF 51/121 reads (42%) | catalogued as rs768704302, COSV53917402; called by muse, mutect2, varscan2
- PFKFB4 | c.1203C>T p.Y401= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV51680131; called by muse, mutect2, varscan2
- PKP3 | c.2013G>A p.Q671= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs142922289; called by muse, mutect2, varscan2
- RRH | c.645C>G p.S215= | Silent (SNP) | VAF 71/153 reads (46%) | catalogued as COSV58490920; called by muse, mutect2, varscan2
- SCNN1G | c.54G>A p.T18= | Silent (SNP) | VAF 27/51 reads (53%) | catalogued as rs372381156; called by muse, mutect2, varscan2
- SIPA1L1 | c.5349C>T p.S1783= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs746880362, COSV62169193; called by muse, mutect2, varscan2
- THBS3 | c.1923G>A p.Q641= | Silent (SNP) | VAF 38/132 reads (29%) | catalogued as COSV64248792; called by muse, mutect2, varscan2
- TRPC3 | c.777C>T p.I259= (on ENST00000379645 / NM_001366479.2; = p.I186= on NM_003305.2) | Silent (SNP) | VAF 37/94 reads (39%) | catalogued as rs201449030, COSV53373268; called by muse, mutect2, varscan2
- ZFYVE19 | c.972A>G p.E324= (on ENST00000355341 / NM_001077268.2; = p.E314= on NM_032850.5) | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV100146416; called by muse, mutect2, varscan2
- FOLH1B | n.1881C>A | RNA (SNP) | VAF 73/165 reads (44%) | called by muse, mutect2, varscan2
